Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KS, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KS-01A (Primary Tumor).

ICD-O-3
Tumor, Adrenal Cortical of unknown/
uncertain behavior 8370/1
Site ④ Adrenal Gland Cortex
Q74.0
JW 2/6/13

Procedure: L adrenalectomy

Gross description: 9 x 9.5 x 9.5cm, 404g

Diagnosis: adrenocortical carcinoma, G2

Per NCI on 4/16/13, case may
ship as long as it is ACC (regardless
of stated behavior). BCR

If case passes, TSS will be
asked for add'l path info. JW

Histology Discrepancy		

Source: NCI Genomic Data Commons file 2a1697e0-62cf-4ce8-9263-b05ea4f5dd1d (TCGA-OR-A5KS.CF5CAAE7-CEA0-4505-A33F-7E7588DB7D7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).